Somatic mutation profile of tumor specimen MMRF_1338_1_BM_CD138pos (aliquot MMRF_1338_1_BM_CD138pos_T1_KAS5U_L00646) from MMRF case MMRF_1338, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 31.0 years (11,322 days).
Specimen MMRF_1338_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73991dd0-a8f2-4e76-8f2b-7e1780f5d505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1338_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1338_1_PB_Whole_C2_KAS5U_L00654; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2925ef0a-d506-441d-9236-77e3fa620765

The open-access MAF lists 61 somatic variants for this specimen: 16 protein-altering or splice-affecting, 12 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 16, Missense Mutation 14, Intron 12, Silent 12, Nonsense Mutation 2, 5'Flank 2, 3'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNB | c.4282G>A p.G1428S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747673269; called by muse, mutect2, varscan2
- FRS3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 31/56 reads (55%) | catalogued as rs779642151; called by muse, mutect2, varscan2
- MEGF8 | c.4202C>T p.S1401L (on ENST00000251268 / NM_001271938.2; = p.S1334L on NM_001410.3) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs768453015, COSV52094838; called by muse, mutect2, varscan2
- MYO3A | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs912569262; called by muse, varscan2
- PTPRD | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as COSV61962191; called by muse, mutect2, varscan2
- TENM3 | c.6593G>A p.R2198H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.98); catalogued as rs201676320, COSV69308961, COSV69312882; called by muse, mutect2
- TIGD3 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs982405240; called by muse, mutect2, varscan2
- ARHGEF33 | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.035); called by muse, mutect2
- C2orf66 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 5/120 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DOK3 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PCF11 | c.2639G>T p.G880V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PGLYRP2 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PPP1R9A | c.2665C>A p.L889I | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SPTBN1 | c.5162C>T p.A1721V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENT5C | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ZDHHC5 | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ARFGEF3 | c.2742C>T p.S914= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV52466033; called by muse, mutect2, varscan2
- CFD | c.579G>A p.L193= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- CXCR5 | c.504C>A p.I168= | Silent (SNP) | VAF 54/132 reads (41%) | called by muse, varscan2
- CXCR5 | c.558C>G p.L186= | Silent (SNP) | VAF 63/159 reads (40%) | catalogued as COSV52682477; called by muse, varscan2
- DOK3 | c.1065C>T p.H355= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs774347697; called by muse, mutect2, varscan2
- GPAA1 | c.795G>A p.L265= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs911001673; called by muse, mutect2, varscan2
- KATNIP | c.750A>G p.G250= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- MAP3K11 | c.39A>G p.L13= | Silent (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2, varscan2
- NLRX1 | c.1020C>T p.V340= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- RBBP8NL | c.687C>T p.S229= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- TTLL2 | c.897C>T p.N299= | Silent (SNP) | VAF 7/153 reads (5%) | catalogued as rs1241868846; called by muse, mutect2
- ZGLP1 | c.15G>A p.Q5= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV58532862; called by muse, mutect2, varscan2
- AKT1 | c.436-35C>T | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- BEND4 | c.*1400A>C | 3'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- C1QL3 | c.*407T>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- CD36 | c.-89-196T>G | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- CMC1 | c.201-176T>C | Intron (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- COG8 | c.*379G>C | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- DMAC1 | chr9:7800089 T>C | 5'Flank (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- DSG2 | c.2335-11T>C | Intron (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- EPC2 | c.*1178A>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, varscan2
- ERCC1 | c.602+10G>A | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+2314A>G | Intron (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- GLYR1 | c.*253T>A | 3'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- GNLY | c.52+197G>A | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- GPAM | c.*3355C>A | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- INPP4B | chr4:142024796 T>C | 3'Flank (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- KMT2A | c.432+2075T>G | Intron (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- MARF1 | chr16:15643493 A>G | 5'Flank (SNP) | VAF 12/30 reads (40%) | called by muse, varscan2
- MLEC | c.*3529A>T | 3'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- MLEC | c.*3530A>C | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- MROH9 | c.*157C>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs1053818506; called by mutect2, varscan2
- NEDD9 | c.-27A>G | 5'UTR (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- NELFCD | c.230+38G>T | Intron (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- OR8J1 | c.*57del | 3'UTR (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- PCSK4 | c.189+119C>G | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.*2176C>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | catalogued as rs543725412; called by muse, mutect2, varscan2
- SETX | c.*431del | 3'UTR (DEL) | VAF 4/36 reads (11%) | catalogued as rs1554801157, COSV56385021; called by pindel, varscan2
- SH3PXD2B | c.*2832G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- SLC22A17 | n.1341C>T | RNA (SNP) | VAF 18/40 reads (45%) | catalogued as rs757846010; called by muse, mutect2, varscan2
- SLCO2A1 | c.*1067C>T | 3'UTR (SNP) | VAF 31/48 reads (65%) | called by muse, mutect2, varscan2
- TET2 | c.3500+522_3500+525del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs1275965916; called by pindel, varscan2
- TPX2 | c.*29G>A | 3'UTR (SNP) | VAF 3/49 reads (6%) | catalogued as rs1238101879, COSV100302203; called by muse, mutect2
- UCMA | c.*29A>G | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- ZC3H13 | c.4672+1005A>G | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
